Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1I4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1I4-06A (Metastatic).

1CD-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9 3/12/11 *hw*

DIAGNOSIS: LEFT PECTORAL MUSCLE
CONSISTENT WITH METASTATIC MALIGNANT MELANOMA

CLINICAL IMPRESSION:
R/O Melanoma

GROSS DESCRIPTION:
55x23x27 mm ellipse cross-sectioned and submitted entirely 1=end, 2=other end representative section submitted

MICROSCOPIC DESCRIPTION:
Within the subcutaneous tissue/skeletal muscle, there are large islands of atypical cells with numerous mitoses and focal areas of necrosis. These atypical cells display focal cytoplasmic melanin pigment. The cells exhibit conspicuous nucleolus, irregular nuclear membrane and moderately abundant cytoplasm.

Final Diagnosis performed by

HI/AA Discrepancy		☒

Source: NCI Genomic Data Commons file 56e5e7dc-00c4-4f72-aea4-b4e416591fbc (TCGA-DA-A1I4.2E4DF07F-4B5A-4CCA-A824-D6FE54D82B0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).